Surgical pathology report (de-identified scan), TCGA case TCGA-B8-5546, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-5546-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Surgical Pathology Report

Diagnosis:

Kidney, right, laparoscopic nephrectomy

Histologic tumor type/subtype: Renal cell carcinoma, clear cell type

Sarcomatoid features: Not identified

Histologic grade (if applicable): Fuhrman grade 2

Tumor size (greatest dimension): 4.3 cm

Tumor focality: Unifocal

Extent of tumor invasion (if present specify if macroscopic or microscopic):

Capsular invasion/perirenal adipose tissue: Not involved

Gerota's fascia: Not involved

Renal sinus: Not involved

Major veins (renal vein or segmental branches, IVC): Not involved

Ureter: Not involved

Venous (large vessel): Not involved

Lymphatic (small vessel): None identified

Histologic assessment of surgical margins:

Gerota's fascia (nephrectomy): Negative

Renal vein (nephrectomy): Negative

Ureter (nephrectomy): Negative

Adrenal gland: not present in specimen

Lymph nodes: none identified

Other significant findings: Angiomyolipoma, 0.3 cm

AJCC Staging:

pT1b

pNX

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

right renal mass.

Gross Description:

Specimen fixation: formalin

Type of specimen: laparoscopic nephrectomy

Side of specimen: right

Size and weight of specimen: 280 g, 13.2 x 10 x 4.3 cm overall composed of a 10.8 x 6.7 x 4.0 cm kidney with attached perinephric fat and 3.6 cm of attached ureter.

Orientation: The posterior surface is marked with blue ink.

Presence/absence of adrenal gland: absent

[page 2 of 2]
Tumor description/site: The tumor is a fleshy tan-pink circumscribed nodule with central red-orange discoloration. It is located in the superior/medial/posterior aspect of the specimen in the cortex. The tumor compresses adjacent cortical tissue and abuts the renal pelvis.

Tumor size: 4.3 x 3.6 x 3.1 cm

Presence/absence of multicentricity: absent

Confinement/non-confinement to the kidney: appears confined to the kidney

Extent of invasion:

Perirenal adipose tissue: tumor grossly does not involve

Gerota's fascia: tumor grossly does not involve

Renal vein: tumor grossly does not involve

Ureter: tumor grossly does not involve

Other organs: n/a

Surgical margins:

Perirenal adipose tissue: within 0.4 cm of the closest blue inked posterior margin (A5)

Renal vein: negative

Renal artery: negative

Ureter: Grossly unremarkable. The pelvic urothelium is white-tan and velvety and the ureter is of normal caliber.

Description of kidney away from tumor: Red-tan-brown grossly unremarkable with an average cortical thickness of 0.7 cm. There is a solitary 0.2 cm white cortical nodule in the superior lateral pole located 4 cm from the edge of the tumor (A4).

Lymph nodes (hilar): none identified

Other significant findings: none

Tissue submitted for special investigations: Tumor and normal are given to tissue procurement.

Digital photograph taken: no

Block Summary:

A1 - ureter and vascular margins of resection

A2 - tumor abutting pelvic urothelium

A3 - tumor towards hilum

A4 - small cortical nodule

A5 - tumor and posterior blue inked soft tissue margin

A6 - tumor and adjacent renal parenchyma

A7 - central tumor with discoloration and softening

A8 - lower pole renal parenchyma away from tumor

Light Microscopy:

Light microscopic examination is performed by [REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 777149a2-546f-4724-a439-1eac7e5c0188 (TCGA-B8-5546.ADE36B12-E111-4A95-BBAC-7D25EA9695D9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).